Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LD, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LD-01A (Primary Tumor).

Procedure: adrenalectomy, left renal vein and LN

Gross description: 17 x 10 x 8cm

Diagnosis: adrenocortical carcinoma, KI67 10%

Reference Pathology:

Diagnosis: adrenocortical carcinoma

Weiss score: 5

Hough score: 3.13

Van Slooten score: 18

ICD-O-3

Carcinoma, adrenal
cortical 8370/3

Site: Adrenal Gland cortex
C74.0

gW 2/6/13

Criteria	W 1/14/13	Yes	No
Dist/Sync/Unknown Primary Noted			

Source: NCI Genomic Data Commons file 05ef87e2-160a-4653-bab4-c0224232401b (TCGA-OR-A5LD.08D3F046-01AD-40B2-A4EC-1121366614CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).